Somatic mutation profile of tumor specimen TCGA-2G-AAFG-01A (aliquot TCGA-2G-AAFG-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAFG, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 30.1 years (11,002 days).
Specimen TCGA-2G-AAFG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 331ccc01-f9b9-4c32-aab9-967851cce8b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAFG-10A (Blood Derived Normal), aliquot TCGA-2G-AAFG-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a57ee253-5b91-4a41-9125-df5a1ff72e83

The open-access MAF lists 18 somatic variants for this specimen: 16 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CBLC | c.429G>T p.K143N | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.16); catalogued as COSV99541816; called by muse, mutect2
- H2AC13 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1166788499; called by muse, mutect2, varscan2
- ITPR3 | c.5092C>G p.R1698G | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs774177342, COSV104428103; called by muse, mutect2, varscan2
- NAP1L3 | c.1058C>G p.P353R | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59077323; called by muse, mutect2, varscan2
- ABCD1 | c.507C>A p.H169Q | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ADGRL2 | c.2755T>A p.F919I (on ENST00000370717 / NM_001366005.1; = p.F906I on NM_012302.4) | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- ARID4B | c.3227G>C p.G1076A | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- C1QBP | c.674C>T p.T225I | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.505); called by muse, mutect2
- HLX | c.693C>G p.N231K | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- LUC7L3 | c.442T>A p.S148T | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- MED12L | c.3875G>A p.C1292Y | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SAFB | c.2396G>T p.G799V | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- TET1 | c.4415C>G p.T1472S | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTF1 | c.1589A>G p.Q530R | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- UBR5 | c.7551G>T p.R2517S | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- ZNF782 | c.434G>T p.C145F | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL21A1 | c.2091+10G>T | Intron (SNP) | VAF 17/98 reads (17%) | called by muse, mutect2, varscan2
- SPATA31C2 | n.348C>A | RNA (SNP) | VAF 12/73 reads (16%) | called by muse, mutect2, varscan2
